Gene-level copy-number profile of tumor specimen C3L-01607-01 from CPTAC case C3L-01607, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 83.4 years (30,462 days).
Specimen C3L-01607-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 293a3cfc-f99f-46a3-8191-5db347652540.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01607-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/53a11902-17cb-414b-999a-858e1d0ec742

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 337; copy number 2: 57,178; copy number 3: 877; copy number 4: 1; copy number 7: 1; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:89,960,422–89,974,072, 2 genes, copy number 10: AP004607.1, TRIM64.
- chr11:89,993,536–89,999,741, 1 gene, copy number 7: TRIM53AP.

Autosomal genes at a single copy (total copy number 1): 108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
